Somatic mutation profile of cancer-model specimen HCM-CSHL-0076-C25-85A (3D Organoid; aliquot HCM-CSHL-0076-C25-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-CSHL-0076-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,308 days).
Specimen HCM-CSHL-0076-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294abd10-00e8-4e6a-8e0a-254563f501e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0076-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0076-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0da42ec-176e-4352-bdb8-e1c9e21e03c0

The open-access MAF lists 69 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Nonsense Mutation 5, Intron 4, RNA 3, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 169/401 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 137/137 reads (100%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-1_787del p.X261_splice | Splice Site (DEL) | VAF 259/295 reads (88%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSM4 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 126/428 reads (29%) | catalogued as rs760878212; called by muse, varscan2
- ADCY8 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs62640020; called by muse, mutect2
- ARHGAP30 | c.3049C>T p.R1017* (on ENST00000368013 / NM_001025598.2; = p.R806* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 92/203 reads (45%) | catalogued as COSV100920252; called by muse, mutect2, varscan2
- BRAT1 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 283/630 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406194043, COSV61397538; called by muse, mutect2, varscan2
- CACNA1I | c.2434G>A p.V812I | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs748634146; called by muse, mutect2, varscan2
- CACNG3 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 77/119 reads (65%) | catalogued as COSV50069711; called by muse, mutect2, varscan2
- CEL | c.2002T>G p.S668A (on ENST00000673714; = p.S665A on NM_001807.6) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs2480922, COSV60827533; called by muse, varscan2
- DNAH9 | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs137877445; called by muse, mutect2, varscan2
- DOCK10 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.999); catalogued as rs748247508; called by muse, mutect2, varscan2
- DSCAM | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs542069235; called by muse, mutect2, varscan2
- EPB41L4A | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201722745; called by muse, mutect2, varscan2
- ESPNL | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775489305; called by muse, mutect2
- KBTBD8 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs772686457, COSV55127499, COSV55128258; called by muse, mutect2, varscan2
- KIF21A | c.4220C>T p.T1407I (on ENST00000361418 / NM_001378440.1; = p.T1394I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV62773380; called by muse, mutect2
- LSP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 132/300 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760171733; called by muse, varscan2
- MAPKBP1 | c.1843C>T p.R615W (on ENST00000456763 / NM_001128608.2; = p.R609W on NM_014994.3) | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs918872385; called by muse, mutect2
- MEGF8 | c.8311G>A p.E2771K (on ENST00000251268 / NM_001271938.2; = p.E2704K on NM_001410.3) | Missense Mutation (SNP) | VAF 52/590 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1193688581; called by muse, mutect2
- RAD17 | c.1553G>A p.G518E (on ENST00000380774 / NM_133339.2; = p.G507E on NM_002873.1) | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs781628659; called by muse, mutect2, varscan2
- RYR1 | c.3556G>A p.G1186S | Missense Mutation (SNP) | VAF 322/937 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1568465251, COSV62089929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP6 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs371874764; called by muse, mutect2, varscan2
- SFMBT2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs372825470; called by muse, mutect2, varscan2
- SLA | c.406C>T p.R136C (on ENST00000338087 / NM_001045556.3; = p.R176C on NM_006748.4) | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200511116, COSV55065123; called by muse, mutect2, varscan2
- SLC22A10 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 96/175 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as rs374740617, COSV100235794; called by muse, mutect2, varscan2
- AATF | c.1507A>T p.K503* | Nonsense Mutation (SNP) | VAF 65/159 reads (41%) | called by muse, mutect2, varscan2
- AKR7L | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4661C>T p.P1554L | Missense Mutation (SNP) | VAF 116/212 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOB | c.13392_13396del p.E4464Dfs*13 | Frame Shift Del (DEL) | VAF 125/290 reads (43%) | called by mutect2, pindel, varscan2
- CCDC15 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CCT8L2 | c.1613A>G p.K538R | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GSN | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 95/393 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRAS | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIPF | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NUTM1 | c.1361A>C p.E454A | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDRG1 | c.193T>G p.F65V | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB33A | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 49/482 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ROR1 | c.1993A>T p.M665L | Missense Mutation (SNP) | VAF 121/202 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD3 | c.841_842insG p.N281Rfs*13 | Frame Shift Ins (INS) | VAF 69/189 reads (37%) | called by mutect2, pindel, varscan2
- SPAG5 | c.1056_1086del p.S353Yfs*64 | Frame Shift Del (DEL) | VAF 130/400 reads (33%) | called by mutect2, pindel, varscan2
- SUSD5 | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- VPS18 | c.687C>A p.F229L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ACSM4 | c.198G>A p.E66= | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, varscan2
- CLIC6 | c.1686A>G p.Q562= (on ENST00000360731 / NM_001317009.2; = p.Q544= on NM_053277.3) | Silent (SNP) | VAF 116/212 reads (55%) | called by muse, mutect2, varscan2
- CMTM6 | c.517A>C p.R173= | Silent (SNP) | VAF 65/114 reads (57%) | called by muse, mutect2, varscan2
- COL4A1 | c.2376C>G p.S792= | Silent (SNP) | VAF 221/511 reads (43%) | catalogued as COSV65422537; called by muse, mutect2, varscan2
- GEMIN4 | c.216C>A p.I72= | Silent (SNP) | VAF 124/124 reads (100%) | called by muse, mutect2, varscan2
- MUC5B | c.489C>T p.G163= | Silent (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- MYH11 | c.2184C>T p.Y728= | Silent (SNP) | VAF 62/803 reads (8%) | catalogued as rs773539549; called by muse, mutect2
- MZF1 | c.1233G>A p.P411= | Silent (SNP) | VAF 139/497 reads (28%) | called by muse, mutect2, varscan2
- OR2A12 | c.600G>A p.A200= | Silent (SNP) | VAF 58/681 reads (9%) | catalogued as rs781479320, COSV68821274; called by muse, mutect2
- PPP1R2 | c.39G>T p.G13= | Silent (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- SLC6A3 | c.570G>A p.S190= | Silent (SNP) | VAF 22/506 reads (4%) | catalogued as rs145813384; called by muse, mutect2
- SORBS1 | c.678C>T p.R226= (on ENST00000361941 / NM_001034954.2; = p.R194= on NM_015385.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as rs764367722; called by muse, mutect2, varscan2
- SRPX2 | c.624G>A p.P208= | Silent (SNP) | VAF 320/786 reads (41%) | catalogued as rs139514583; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- SSC5D | c.276C>T p.N92= | Silent (SNP) | VAF 140/375 reads (37%) | catalogued as rs764456516; called by muse, mutect2, varscan2
- UNC13A | c.1965G>A p.A655= | Silent (SNP) | VAF 217/554 reads (39%) | catalogued as rs777063829, COSV53191454; called by muse, mutect2, varscan2
- AC139495.2 | n.1012C>T | RNA (SNP) | VAF 30/257 reads (12%) | catalogued as rs533397752; called by muse, mutect2, varscan2
- ACAP3 | c.751-20G>A | Intron (SNP) | VAF 29/219 reads (13%) | called by muse, mutect2, varscan2
- AL450442.1 | n.673C>A | RNA (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- H2BP2 | chr1:143876149 G>A | 3'Flank (SNP) | VAF 344/1193 reads (29%) | called by muse, mutect2, varscan2
- HPR | c.-26C>T | 5'UTR (SNP) | VAF 113/399 reads (28%) | catalogued as rs763809585; called by muse, mutect2, varscan2
- KMT5B | c.1174+1071G>T | Intron (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- LGI1 | c.504-36C>T | Intron (SNP) | VAF 188/380 reads (49%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12911G>A | Intron (SNP) | VAF 100/100 reads (100%) | catalogued as rs1350071736; called by muse, mutect2, varscan2
- TBC1D29P | n.2919G>A | RNA (SNP) | VAF 98/260 reads (38%) | catalogued as rs778454288; called by muse, mutect2, varscan2
- TMEM131L | c.-42C>T | 5'UTR (SNP) | VAF 29/84 reads (35%) | catalogued as rs574469145; called by muse, mutect2, varscan2
- ZNF747 | c.*38G>T | 3'UTR (SNP) | VAF 120/361 reads (33%) | called by muse, mutect2, varscan2
